Somatic mutation profile of tumor specimen ALCH-B1LN-TTP1-A (aliquot ALCH-B1LN-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1LN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-B1LN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f834aad9-c460-42ab-850b-b5ce70e52f9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LN-NB1-A (Blood Derived Normal), aliquot ALCH-B1LN-NB1-A-2-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25907f06-3ebb-4ac5-ac2e-f842062f6e42

The open-access MAF lists 89 somatic variants for this specimen: 50 protein-altering or splice-affecting, 30 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 30, Nonsense Mutation 7, Intron 3, RNA 3, 3'UTR 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 112/613 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 36/459 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52364820; called by muse, mutect2
- ATG2A | c.5210G>T p.R1737L | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65968231; called by muse, mutect2
- BUD23 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781881214; called by muse, mutect2, varscan2
- CRX | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs567851258; called by muse, mutect2
- FAM117B | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1265221165; called by muse, mutect2
- HLA-A | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 30/326 reads (9%) | catalogued as rs199474547; called by muse, mutect2
- IGF2R | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV100807192, COSV63632369; called by muse, mutect2
- IPO13 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 39/437 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs746066696; called by muse, mutect2
- ISLR2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV100679605, COSV100679631; called by muse, mutect2
- MAGEB2 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1396356517, COSV66780228, COSV66781776; called by muse, varscan2
- PCDHGA12 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV52754069; called by muse, mutect2
- PDE8B | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 72/685 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV53737323; called by muse, mutect2
- POLQ | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs773624174, COSV51747978; called by muse, mutect2, varscan2
- PTPN5 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 24/221 reads (11%) | catalogued as rs761092772, COSV104422798; called by muse, mutect2, varscan2
- SLFN11 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 22/249 reads (9%) | catalogued as rs1278435784; called by muse, mutect2
- TET3 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs749919860; called by muse, mutect2, varscan2
- TNR | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs1311851968, COSV54886924; called by muse, mutect2
- ZNF100 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59749712; called by muse, mutect2
- ZNF860 | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV64384577; called by muse, varscan2
- BAG3 | c.1051G>T p.V351F | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C1R | c.2074del p.I692Sfs*34 (on ENST00000536053 / NM_001354346.2; = p.I678Sfs*34 on NM_001733.7) | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- CDC42 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DYSF | c.2624T>A p.L875Q | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF2A | c.1613A>C p.K538T | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EVPL | c.2806G>T p.E936* | Nonsense Mutation (SNP) | VAF 35/193 reads (18%) | called by muse, mutect2, varscan2
- FAT4 | c.9224C>A p.A3075E | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2
- FST | c.968C>A p.T323N | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- GABRA3 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPN2 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- IGLV1-40 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KAT8 | c.425A>C p.Q142P | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- KLHL42 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.229); called by muse, mutect2
- LRRN2 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LTN1 | c.2033T>C p.F678S | Missense Mutation (SNP) | VAF 37/386 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- MPHOSPH10 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- MTMR9 | c.359T>A p.I120K | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- OR1N2 | c.213A>T p.L71F | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PURG | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- RFX7 | c.1364G>T p.C455F (on ENST00000559447 / NM_001368074.1; = p.C552F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/519 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SAMD1 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SETD1B | c.3188C>G p.S1063W | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SHROOM2 | c.2177A>T p.H726L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- SLC28A1 | c.579T>A p.F193L | Missense Mutation (SNP) | VAF 151/648 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- STYXL2 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- TGIF2LX | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 58/550 reads (11%) | called by muse, mutect2
- THSD1 | c.743C>A p.P248Q | Missense Mutation (SNP) | VAF 51/476 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TRIM64B | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 51/1218 reads (4%) | called by muse, mutect2
- WDR19 | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF354C | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG8 | c.642G>T p.S214= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV55390484; called by muse, mutect2
- ACE | c.3057G>T p.G1019= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- AKAP3 | c.1002C>T p.I334= | Silent (SNP) | VAF 102/422 reads (24%) | catalogued as rs769260852, COSV57420181; called by muse, mutect2, varscan2
- ANKRD30B | c.1893C>A p.A631= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ATMIN | c.1380G>A p.Q460= | Silent (SNP) | VAF 30/290 reads (10%) | catalogued as rs761902495; called by muse, mutect2, varscan2
- BAHCC1 | c.816C>T p.A272= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1242954713; called by muse, varscan2
- CCKAR | c.1188G>A p.A396= | Silent (SNP) | VAF 33/293 reads (11%) | catalogued as rs1329111614; called by muse, mutect2, varscan2
- CD96 | c.987A>G p.G329= (on ENST00000283285 / NM_198196.3; = p.G313= on NM_005816.5) | Silent (SNP) | VAF 40/321 reads (12%) | called by muse, mutect2, varscan2
- CELSR3 | c.9628C>A p.R3210= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV99373327; called by muse, mutect2
- CMKLR1 | c.1056C>T p.S352= (on ENST00000312143 / NM_001142344.2; = p.S350= on NM_004072.3) | Silent (SNP) | VAF 34/298 reads (11%) | catalogued as rs1212388569; called by muse, mutect2, varscan2
- DSG1 | c.297C>A p.I99= | Silent (SNP) | VAF 42/426 reads (10%) | catalogued as COSV57133936; called by muse, mutect2
- EFCAB10 | c.321T>C p.D107= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs200413293; called by muse, mutect2
- EVPL | c.2805G>C p.L935= | Silent (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- FOLH1 | c.1179T>A p.A393= | Silent (SNP) | VAF 50/421 reads (12%) | called by muse, mutect2, varscan2
- GPR150 | c.381G>A p.L127= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, varscan2
- GRM6 | c.2487G>T p.S829= | Silent (SNP) | VAF 48/442 reads (11%) | catalogued as COSV51437158; called by muse, mutect2, varscan2
- GRPR | c.345G>T p.L115= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- H2BW1 | c.298C>A p.R100= | Silent (SNP) | VAF 30/354 reads (8%) | catalogued as COSV54219980; called by muse, mutect2
- KRT76 | c.756G>A p.R252= | Silent (SNP) | VAF 116/544 reads (21%) | catalogued as rs1339317854; called by muse, mutect2, varscan2
- LOXL2 | c.273C>T p.H91= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs200700018; called by muse, mutect2, varscan2
- REG3A | c.48C>A p.S16= | Silent (SNP) | VAF 32/406 reads (8%) | catalogued as COSV59408204; called by muse, mutect2
- RXYLT1 | c.81C>G p.V27= | Silent (SNP) | VAF 37/481 reads (8%) | catalogued as rs971441689; called by muse, mutect2
- RYR2 | c.3960A>T p.G1320= | Silent (SNP) | VAF 28/292 reads (10%) | called by muse, mutect2
- SFSWAP | c.1413C>T p.G471= | Silent (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- SLC25A19 | c.114C>T p.V38= | Silent (SNP) | VAF 50/655 reads (8%) | catalogued as COSV57466890; called by muse, mutect2
- SLC6A4 | c.1662C>T p.C554= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs751132654; called by muse, mutect2, varscan2
- SMCHD1 | c.5088A>C p.L1696= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- STYXL2 | c.1227G>T p.R409= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- TAF5 | c.576G>C p.V192= | Silent (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.1275T>A p.G425= | Silent (SNP) | VAF 22/355 reads (6%) | called by muse, mutect2
- AP003548.1 | n.450T>C | RNA (SNP) | VAF 41/353 reads (12%) | called by muse, mutect2, varscan2
- C4orf50 | c.-1256T>A | 5'UTR (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
- DDR1 | c.-43+70A>G | Intron (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- FMR1 | c.*868G>T | 3'UTR (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- LINC02874 | n.367C>T | RNA (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2, varscan2
- MIB2 | c.1586-35C>T | Intron (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- PCBP4 | c.387+82C>T | Intron (SNP) | VAF 40/301 reads (13%) | called by muse, mutect2, varscan2
- RPLP0P2 | n.830G>T | RNA (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- TNPO2 | c.*2011G>A | 3'UTR (SNP) | VAF 18/174 reads (10%) | catalogued as rs527784359, COSV63510236; called by muse, mutect2
